CCDI case PBBVUE — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/9e2b7ba2-7434-4bce-81f6-3f34fcde59ef

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Craniopharyngioma, adamantinomatous: ICD-O-3 morphology code: 9351/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.3 years (1,583 days).

Biospecimens (2 samples)
- Sample 0DITSY: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DITTX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
